Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8534, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8534-01A (Primary Tumor).

[page 1 of 5]
HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain ; tired of eating

Symptoms: Blood in the stool ; weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink / day	15 (yrs)	6 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	x An ulceration was seen at the lesser curvature	
MRI		
Biopsy	Adenocarcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T3 N0 M0 Stage: II		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach tumor	Antrum	5 x 4 x 1.5 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3		N0	M0
		Stage:	II

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach tumor	5 x 4 x 1.5 cm	Anterior	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃	N ₀	M ₀	Stage: II

Notes:

[page 5 of 5]
1. Histological pattern:

CELL DISTRIBUTION		STRUCTURAL PATTERN	
Diffuse	☒	Streaming	☐
Mosaic	☒	Storiform	☐
Necrosis	☒	Fibrosis	☐
Lymphocytic Infiltration	☒	Palisading	☐
Vascular Invasion	☐	Cystic Degeneration	☐
Clusterized	☐	Bleeding	☐
Alveolar Formation	☒	Myxoid Change	☐
Indian File	☐	Psammoma/Calcification	☐

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		
Otherwise Specified: D ₁ 70% D ₂ 65% D ₃ 65% D ₄ 75%											

2. Cellular Differentiation:

Well	Moderately	Poor
		☒

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				☒
Hyperchromatism				☒
Nucleolar Prominent				☒
Multinucleated Giant Cell				☒
Mitotic Activity				☒
Nuclear Grade				☒

Histological Diagnosis: Diffuse poorly differentiated Adenocarcinoma

Comments: _____

Source: NCI Genomic Data Commons file 32ac5704-6313-4d0b-ae30-087b870e29b3 (TCGA-CD-8534.18700E36-D1EA-4673-8D4D-3130077FE619.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).